Somatic mutation profile of tumor specimen 0DYKSD from CCDI case PBCSPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 4.8 years (1,738 days).
Specimen 0DYKSD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59e6d38e-c6d4-4839-bf3e-68b2e571a5f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYKRJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af6cd6dc-ced4-469d-a00c-06c7c5aa83e1

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRS | c.4475G>A p.R1492Q | Missense Mutation (SNP) | VAF 388/1097 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs770889503, CM155628, COSV53625667; called by muse, mutect2, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 20/748 reads (3%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2
- HPCAL1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 380/900 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV57147810; called by muse, mutect2, varscan2
- KCNH3 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 298/1171 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1192975611, COSV57792426; called by muse, mutect2, varscan2
- MAST2 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 428/1356 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs377616815; called by muse, mutect2, varscan2
- RBM10 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 211/305 reads (69%) | catalogued as COSV61308434; called by muse, mutect2, varscan2
- SLC22A12 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 139/492 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1461558168; called by muse, mutect2, varscan2
- DCDC1 | c.2212G>A p.G738R | Missense Mutation (SNP) | VAF 490/1474 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ID3 | c.13A>T p.S5C | Missense Mutation (SNP) | VAF 209/395 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYH14 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 19/778 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUTM2F | c.2052A>T p.R684S | Missense Mutation (SNP) | VAF 438/1534 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SF3B3 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 58/1746 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2
- UNC5A | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 76/713 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- VIPAS39 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 354/1342 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRA3 | c.1068C>T p.N356= | Silent (SNP) | VAF 505/1472 reads (34%) | called by muse, mutect2, varscan2
- BNC2 | c.1818G>A p.P606= | Silent (SNP) | VAF 411/1054 reads (39%) | catalogued as rs142872531; called by muse, mutect2, varscan2
- CFAP251 | c.2281C>T p.L761= | Silent (SNP) | VAF 357/1056 reads (34%) | called by muse, mutect2, varscan2
- KIDINS220 | c.3198T>C p.R1066= | Silent (SNP) | VAF 96/641 reads (15%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1170G>A p.T390= | Silent (SNP) | VAF 51/2107 reads (2%) | catalogued as rs782407936; called by muse, mutect2
- COL27A1 | c.-79C>G | 5'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- VNN3 | c.*306C>T | 3'UTR (SNP) | VAF 395/1037 reads (38%) | catalogued as rs767404158, COSV99258244; called by muse, mutect2, varscan2
